Somatic mutation profile of tumor specimen TCGA-EL-A3ZP-01A (aliquot TCGA-EL-A3ZP-01A-11D-A23M-08) from TCGA case TCGA-EL-A3ZP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 19.4 years (7,101 days).
Specimen TCGA-EL-A3ZP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42fc96a0-f339-480a-a421-b9857fb79de3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3ZP-11A (Solid Tissue Normal), aliquot TCGA-EL-A3ZP-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d48c59e9-4a2e-4b06-83d3-9b64063ff343

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPARGC1A | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs757606579, COSV99337594; called by muse, mutect2, varscan2
- SH3PXD2B | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs1193667826, COSV100287807; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.1039T>C p.F347L | Missense Mutation (SNP) | VAF 59/154 reads (38%) | PolyPhen probably damaging (0.958); catalogued as rs1395979783, COSV99833314; called by muse, mutect2, varscan2
- XDH | c.2758G>C p.G920R | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1008705348; called by muse, mutect2
- TP53BP2 | c.1518T>G p.P506= (on ENST00000343537 / NM_001031685.3; = p.P377= on NM_005426.2) | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100636542; called by muse, mutect2, varscan2
